Somatic mutation profile of tumor specimen TCGA-EJ-A7NJ-01A (aliquot TCGA-EJ-A7NJ-01A-22D-A34U-08) from TCGA case TCGA-EJ-A7NJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.5 years (21,748 days).
Specimen TCGA-EJ-A7NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8777246f-83ca-4e48-9703-51dea947bf1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NJ-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NJ-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67658341-31f7-4996-bf32-9abac01cf512

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADGRV1 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985652; called by muse, mutect2
- KCNH8 | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100110734, COSV60462775; called by muse, mutect2
- UBASH3A | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99369817; called by muse, mutect2
